Somatic mutation profile of tumor specimen 0DU816 from CCDI case PBCJSV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (395 days).
Specimen 0DU816: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4470ac57-e12e-420c-9f56-ffe107ecc701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU806 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca46cc77-f8d1-44a0-a62f-dd64505fe096

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.463C>T p.R155* (on ENST00000263121; = p.R201* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 582/1378 reads (42%) | catalogued as rs1555877286, CM992975, COSV54093216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PARD6A | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 199/942 reads (21%) | catalogued as rs1488873633, COSV54671055; called by muse, mutect2, varscan2
- PIK3R5 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 66/1174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553912690, COSV104369355; called by muse, mutect2
- GTF3C3 | c.1818_1830del p.N606Kfs*11 | Frame Shift Del (DEL) | VAF 132/1040 reads (13%) | called by mutect2, varscan2
- MAJIN | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 392/1042 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARNTL2 | c.1542T>C p.G514= | Silent (SNP) | VAF 26/1014 reads (3%) | called by muse, mutect2
- GPAA1 | c.1266G>T p.V422= | Silent (SNP) | VAF 986/2202 reads (45%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1143C>T p.F381= | Silent (SNP) | VAF 292/1720 reads (17%) | catalogued as rs1330603072; called by muse, mutect2, varscan2
- TYR | c.1458C>A p.A486= | Silent (SNP) | VAF 766/1656 reads (46%) | catalogued as COSV54480361; called by mutect2, varscan2
